Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3329, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3329-01A (Primary Tumor).

[page 1 of 2]
MRN: [REDACTED] Hospital
[REDACTED] IP
[REDACTED] MD
Age: [REDACTED] Sex: [REDACTED]
DOB: [REDACTED] Laboratory Patient Report
Print Date/Time: [REDACTED] 8

Surgical Pathology

Histopathological Examination

Path#: [REDACTED]
Collected: [REDACTED] Received: [REDACTED] Complete: [REDACTED]

Pre-Op Diagnosis : Right Renal Mass
Order Physician : [REDACTED] MD
Specimens : Kidney, Right
Frozen Diagnosis :

Report : GROSS EXAMINATION:
The specimen is received in a container labeled with the name of the patient and labeled as kidney, right. The specimen consists of a kidney and attached perinephric fat which measures en bloc 14 x 10 x 5 cm and weighs 405 g. The ureter and vascular margins of resection are submitted in block 1. The kidney is sectioned and shows a golden yellow mass in the superior pole which measures 6.5 cm. The mass is focally adherent to the capsule but does not grossly extend through the capsule. Sections of the capsule are submitted in block 2. Sections of the mass are submitted in block 3-7. The pelvis and calices are not grossly dilated. The cortex averages 0.7 cm. A random section of kidney is submitted in block 8. The attached fat is dissected and no lymph nodes or adrenal tissue are identified. [REDACTED]

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

SPECIMEN TYPE: Radical nephrectomy.
LATERALITY: Right.
TUMOR SITE: Upper pole.
FOCALITY: Unifocal.
TUMOR SIZE (LARGEST TUMOR IF MULTIPLE): 6.5 cm.
MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney.
HISTOLOGIC TYPE: Clear cell (conventional) renal carcinoma.
HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): Grade II.
EXTENT OF INVASION
PRIMARY TUMOR (PT): pT1b: Tumor more than 4 cm but not more than 7 cm in greatest dimension limited to the kidney.
REGIONAL LYMPH NODES (PN): pNX: Cannot be assessed
DISTANT METASTASIS (PM): pMX: Cannot be assessed
MARGINS: Uninvolved by invasive carcinoma.
ADRENAL GLAND: Not present.
VENOUS (LARGE VESSEL) INVASION (V): Absent.

THIS CONFIDENTIAL
FEDERAL AN

THIS DOCUMENT/INFORMATION IS PROTECTED BY
AUTHORIZED DISCLOSURE, DISSEMINATION
THIS INFORMATION IS PROHIBITED

MR#: [REDACTED]
Path #: [REDACTED]
Visit #: [REDACTED]

[page 2 of 2]
LYMPHATIC (SMALL VESSEL) INVASION (L): Absent.
ADDITIONAL PATHOLOGIC FINDINGS: None identified.
Intradepartmental consultation obtained.

[REDACTED] M.D., Pathologist

[T-71000 M-83103 189.0 P3-44070]

Electronically Signed by:
[REDACTED], MD

[REDACTED]

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

MR#: [REDACTED] Path #: [REDACTED]
Visit #: [REDACTED]

Page 2 of 2

Source: NCI Genomic Data Commons file 8dfb8ecb-3794-46b6-ae19-3aacd7f76d12 (TCGA-A3-3329.8363A252-7BCB-4415-B386-985138F2E6CF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).